Somatic mutation profile of tumor specimen MP2PRT-PASVHC-TMP1-A (aliquot MP2PRT-PASVHC-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASVHC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,154 days).
Specimen MP2PRT-PASVHC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50006c28-d72c-4cc4-9401-3a0f55a7130c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVHC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVHC-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a725c38a-0c42-41dd-858e-7a0be4b14312

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRACD | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs552787892, COSV51714366; called by muse, mutect2
- EPPK1 | c.5545G>C p.A1849P | Missense Mutation (SNP) | VAF 82/748 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- JAK1 | c.1936_1938dup p.S646dup | In Frame Ins (INS) | VAF 54/434 reads (12%) | called by mutect2, pindel, varscan2
- PARD6G | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CFAP20 | c.435C>A p.G145= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as COSV52630569; called by muse, mutect2, varscan2
- KATNAL1 | c.126A>C p.S42= | Silent (SNP) | VAF 22/434 reads (5%) | catalogued as rs1012792245; called by muse, mutect2
